Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4913, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4913-01A (Primary Tumor).

Surgery Date: [REDACTED]

TCGA-CJ-4913

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY, ADRENAL AND PERIHILAR LYMPH NODES:
RENAL CELL CARCINOMA, CONVENTIONAL (50% CLEAR CELLS AND 50% EOSINOPHILIC CELLS) WITH
FOCAL RHABDOID CELLS, FUHRMAN'S NUCLEAR GRADE 4.
TUMOR EXTENDS INTO THE RENAL SINUS ADIPOSE TISSUE.
TUMOR MEASURES 6.3 CM IN MAXIMUM DIMENSION.
VASCULAR/LYMPHATIC INVASION PRESENT.
Vascular, ureteral and soft tissue margins of resection free of tumor.
Adrenal gland, no tumor present.

GROSS DESCRIPTION

(A) LEFT KIDNEY, ADRENAL GLAND AND PERIHILAR LYMPH NODES - A 19.5 x 11.5 x 5.7 cm nephrectomy specimen including a 13.8 x 8.0 x 5.3 cm kidney with attached 9.5 x 0.5 cm ureter and overlying 5.5 x 2.4 x 0.5 cm adrenal gland.

There is a 6.3 x 5.5 x 5.4 cm, well-circumscribed yellow-tan, hemorrhagic and necrotic tumor in the upper pole. The tumor is grossly appears to be confined to within the kidney but focally pushing the renal sinus adipose tissue. The renal pelvis and renal hilum is uninvolved by tumor, as well as is the renal vein, renal artery and renal ureter. The surgical margins of resection are free of tumor. No lymph nodes are identified in the hilum of the kidney.

Portions of tumor and normal parenchyma are submitted to tissue bank. Portion of tumor is submitted to possible electron microscopic studies.

SECTION CODE: A1, renal artery, renal vein and renal ureter margin (en face); A2, A3, representative sections of tumor in relationship to renal pelvis/hilum; A4, A5, representative sections of tumor in relationship to overlying capsule; A6-A8, additional sections of tumor; A9, normal renal parenchyma; A10, normal adrenal gland. [REDACTED]

CLINICAL HISTORY

Mass, renal left.

SNOMED CODES

T-71000, M-83123, T-B3000, M-00110

Source: NCI Genomic Data Commons file 23a30f65-7329-40da-acb8-2595b35393b9 (TCGA-CJ-4913.BE689986-3BC9-404E-B1BF-5593A2F0380D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).